Somatic mutation profile of tumor specimen TCGA-A5-A0GH-01A (aliquot TCGA-A5-A0GH-01A-21W-A062-09) from TCGA case TCGA-A5-A0GH, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 57.7 years (21,090 days).
Specimen TCGA-A5-A0GH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb8b373f-240b-4a27-8d66-f1cef925ccd7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-A0GH-10A (Blood Derived Normal), aliquot TCGA-A5-A0GH-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a9e5dbc-a968-4295-929f-b2137dd30dbd

The open-access MAF lists 575 somatic variants for this specimen: 433 protein-altering or splice-affecting, 126 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 261, Silent 126, Frame Shift Del 121, Frame Shift Ins 19, Nonsense Mutation 13, Intron 8, Splice Site 8, In Frame Del 5, Splice Region 3, RNA 3, 3'UTR 2, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEP290 | c.6869del p.N2290Ifs*11 | Frame Shift Del (DEL) | VAF 22/38 reads (58%) | catalogued as rs587783017, CD075343; ClinVar: pathogenic; called by mutect2, varscan2
- DICER1 | c.5438A>G p.E1813G | Missense Mutation (SNP) | VAF 279/629 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58615258, COSV58615306, COSV58615741; called by muse, mutect2, varscan2
- DYRK1A | c.452dup p.N151Kfs*12 | Frame Shift Ins (INS) | VAF 65/198 reads (33%) | catalogued as rs797044523; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DYSF | c.4200del p.I1401Sfs*47 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | catalogued as rs398123786, CM053841; ClinVar: pathogenic; called by mutect2, pindel
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 86/218 reads (39%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PEX1 | c.1108dup p.I370Nfs*2 | Frame Shift Ins (INS) | VAF 84/195 reads (43%) | catalogued as rs61750406; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PIK3R2 | c.1117G>A p.G373R | Missense Mutation (SNP) | VAF 10/25 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587776934, CM126686, COSV55846573; ClinVar: pathogenic; called by muse, varscan2
- TRIO | c.3657dup p.C1220Mfs*7 | Frame Shift Ins (INS) | VAF 79/160 reads (49%) | catalogued as rs1554068529; ClinVar: likely pathogenic; called by mutect2, varscan2
- TSC2 | c.488_489del p.F163Cfs*25 | Frame Shift Del (DEL) | VAF 18/82 reads (22%) | catalogued as rs137854122; ClinVar: not provided / pathogenic; called by mutect2, pindel, varscan2
- ABCA12 | c.4025T>G p.L1342R (on ENST00000272895 / NM_173076.3; = p.L1024R on NM_015657.3) | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55978356; called by muse, mutect2, varscan2
- ABCE1 | c.1600G>A p.V534I | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as COSV56849283; called by muse, mutect2, varscan2
- AC109583.1 | c.631A>G p.K211E | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as rs758464196, COSV58406788; called by muse, mutect2, varscan2
- ADD3 | c.1463C>A p.P488Q | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV53326573; called by muse, mutect2, varscan2
- ADGRF5 | c.614T>C p.F205S | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51941330; called by muse, mutect2, varscan2
- ADGRG4 | c.4127del p.L1376Cfs*21 | Frame Shift Del (DEL) | VAF 366/899 reads (41%) | catalogued as rs748603011; called by mutect2, pindel, varscan2
- ADRA1A | c.1209G>A p.M403I | Missense Mutation (SNP) | VAF 152/354 reads (43%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV52375701; called by muse, mutect2, varscan2
- AGA | c.578C>A p.P193H | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV52807787; called by muse, mutect2, varscan2
- AGPS | c.1618C>A p.L540I | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.58); catalogued as COSV51569818; called by muse, mutect2, varscan2
- AHR | c.2387A>C p.Q796P | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.634); catalogued as COSV54126916; called by muse, varscan2
- AKAP5 | c.294A>C p.Q98H | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.814); catalogued as COSV57743157; called by muse, mutect2, varscan2
- ALDH1A3 | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.472); catalogued as rs1036217972, COSV60903583; called by muse, mutect2, varscan2
- ALDH1L1 | c.1157A>G p.D386G | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV56420030; called by muse, mutect2, varscan2
- ALPK2 | c.1568del p.K523Rfs*15 | Frame Shift Del (DEL) | VAF 120/307 reads (39%) | catalogued as rs1341338515; called by mutect2, pindel, varscan2
- AMOTL2 | c.680C>A p.T227N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV51441273; called by muse, mutect2
- AMY2B | c.1496A>T p.E499V | Missense Mutation (SNP) | VAF 184/837 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.358); catalogued as COSV63717353; called by muse, mutect2, varscan2
- ANKRD20A1 | c.1376del p.N459Ifs*5 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as rs1296524808; called by mutect2, varscan2
- ANKS1A | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64465082; called by muse, mutect2, varscan2
- AP4E1 | c.1967-1G>A p.X656_splice | Splice Site (SNP) | VAF 43/204 reads (21%) | catalogued as COSV55920653; called by muse, mutect2, varscan2
- AP5Z1 | c.931C>T p.R311* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as rs376075583; called by muse, mutect2, varscan2
- APBB2 | c.1739C>T p.P580L (on ENST00000295974 / NM_001166050.2; = p.P581L on NM_004307.2) | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55964323; called by muse, mutect2, varscan2
- APC | c.5612_5614dup p.D1871dup | In Frame Ins (INS) | VAF 94/220 reads (43%) | catalogued as rs779014936; called by mutect2, varscan2
- APMAP | c.569C>T p.T190I | Missense Mutation (SNP) | VAF 81/175 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV54177347; called by muse, mutect2, varscan2
- APPL2 | c.1781A>G p.Y594C | Missense Mutation (SNP) | VAF 109/235 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51594756; called by muse, mutect2, varscan2
- ARHGAP30 | c.2603C>T p.A868V | Missense Mutation (SNP) | VAF 80/175 reads (46%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs538155601, COSV63516821; called by muse, mutect2, varscan2
- ARID1A | c.3977del p.P1326Rfs*155 | Frame Shift Del (DEL) | VAF 58/169 reads (34%) | catalogued as COSV61372705; called by mutect2, pindel, varscan2
- ARID1A | c.5791G>T p.E1931* | Nonsense Mutation (SNP) | VAF 153/348 reads (44%) | catalogued as COSV61390343, COSV61390474; called by muse, mutect2, varscan2
- ART1 | c.735del p.F246Lfs*6 | Frame Shift Del (DEL) | VAF 15/40 reads (38%) | catalogued as rs762428866, COSV99167258; called by mutect2, pindel, varscan2
- ASB16 | c.53T>C p.L18P | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53236594; called by mutect2, varscan2
- ASCC3 | c.2442G>T p.W814C | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61234564; called by muse, mutect2, varscan2
- ASF1A | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.926); catalogued as rs755432972, COSV57648976; called by muse, mutect2, varscan2
- ATAD2 | c.354del p.E119Kfs*8 | Frame Shift Del (DEL) | VAF 144/243 reads (59%) | catalogued as rs746676748; called by mutect2, varscan2
- ATOH1 | c.599C>T p.T200I | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60038919; called by muse, mutect2, varscan2
- ATP2B3 | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.084); catalogued as COSV54863671; called by muse, mutect2, varscan2
- ATP2C1 | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV60763563; called by muse, mutect2, varscan2
- ATP6V1E2 | c.373C>T p.L125F | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0.02); catalogued as COSV60576757; called by muse, mutect2, varscan2
- ATP8B2 | c.308T>C p.I103T (on ENST00000672630; = p.I70T on NM_001005855.2) | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59249547; called by muse, mutect2, varscan2
- ATXN2L | c.2997del p.Q1002Kfs*50 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs1288664341; called by mutect2, pindel
- ATXN2L | c.3225G>T p.E1075D | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs1363040251, COSV57365024; called by muse, mutect2, varscan2
- BCAR3 | c.1156G>A p.A386T | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs780475040, COSV53079972; called by muse, mutect2, varscan2
- BFAR | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.173); catalogued as rs772889819, COSV55494718; called by muse, mutect2, varscan2
- BMX | c.1912T>C p.S638P | Missense Mutation (SNP) | VAF 71/162 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV59594047; called by muse, mutect2, varscan2
- C3orf56 | c.449C>A p.S150Y | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.761); catalogued as COSV67756557; called by muse, mutect2, varscan2
- C7orf25 | c.197G>A p.S66N | Missense Mutation (SNP) | VAF 71/186 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV63274326; called by muse, mutect2, varscan2
- CABIN1 | c.4765G>A p.V1589M | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as rs1176319296, COSV54090248; called by muse, mutect2
- CABIN1 | c.4868T>C p.L1623P | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV54090260; called by muse, mutect2, varscan2
- CACNA1D | c.2042C>T p.T681M (on ENST00000350061 / NM_001128840.3; = p.T701M on NM_000720.4) | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT tolerated (0.32); PolyPhen benign (0.199); catalogued as rs369605872, COSV55467215; called by muse, mutect2, varscan2
- CACTIN | c.2198G>A p.R733H | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as rs1451053631, COSV50274532; called by muse, mutect2, varscan2
- CAMTA2 | c.2597del p.P866Lfs*9 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | catalogued as rs745547658; called by mutect2, varscan2
- CAPS2 | c.1452+2T>C p.X484_splice | Splice Site (SNP) | VAF 40/99 reads (40%) | catalogued as COSV60829759; called by muse, mutect2, varscan2
- CASP5 | c.1096C>T p.H366Y | Missense Mutation (SNP) | VAF 154/329 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as rs781677689, COSV52832361, COSV99508074; called by muse, mutect2, varscan2
- CASR | c.2497C>A p.P833T (on ENST00000490131; = p.P910T on NM_000388.4) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.12); catalogued as COSV56141975; called by muse, mutect2, varscan2
- CCDC127 | c.584C>G p.S195C | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.518); catalogued as COSV57258251; called by muse, mutect2, varscan2
- CCDC127 | c.583T>A p.S195T | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.053); catalogued as COSV57258259; called by muse, mutect2, varscan2
- CCDC160 | c.845A>C p.K282T | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV66252031; called by muse, mutect2, varscan2
- CCDC174 | c.350_352del p.K117del | In Frame Del (DEL) | VAF 64/152 reads (42%) | catalogued as rs1167538306; called by pindel, varscan2
- CCDC27 | c.1915dup p.L639Pfs*? | Frame Shift Ins (INS) | VAF 18/46 reads (39%) | catalogued as rs751021664; called by mutect2, varscan2
- CCDC59 | c.724T>C p.*242Qext*26 | Nonstop Mutation (SNP) | VAF 57/130 reads (44%) | catalogued as COSV56280748; called by muse, mutect2, varscan2
- CCL8 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.67); catalogued as COSV67013805; called by muse, mutect2, varscan2
- CDH23 | c.753G>A p.P251= | Splice Region (SNP) | VAF 22/44 reads (50%) | catalogued as rs769896655, COSV54955576, COSV99821780; called by muse, varscan2
- CDK4 | c.521T>G p.V174G | Missense Mutation (SNP) | VAF 117/246 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as COSV56986858; called by muse, mutect2, varscan2
- CDKAL1 | c.749T>C p.V250A | Missense Mutation (SNP) | VAF 75/168 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV51193904; called by muse, mutect2, varscan2
- CFAP47 | c.271C>G p.L91V | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.139); catalogued as COSV52892747; called by muse, mutect2, varscan2
- CFAP54 | c.7415C>A p.S2472Y | Missense Mutation (SNP) | VAF 10/280 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1475408891, COSV61575911; called by muse, mutect2
- CFAP61 | c.2251G>C p.A751P | Missense Mutation (SNP) | VAF 60/125 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV55649771; called by muse, mutect2, varscan2
- CIP2A | c.2108C>T p.A703V | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as rs1016784827, COSV55421712; called by muse, mutect2, varscan2
- CLIP1 | c.3646del p.R1216Efs*6 (on ENST00000620786 / NM_001247997.1; = p.R1205Efs*6 on NM_002956.2) | Frame Shift Del (DEL) | VAF 20/53 reads (38%) | catalogued as rs761972338; called by mutect2, pindel, varscan2
- CMTM3 | c.304-2A>G p.X102_splice | Splice Site (SNP) | VAF 5/9 reads (56%) | catalogued as rs1347619472, COSV62680478; called by muse, mutect2, varscan2
- CNOT1 | c.1888G>A p.G630R | Missense Mutation (SNP) | VAF 69/162 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as rs150528737; called by muse, mutect2, varscan2
- CNPPD1 | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs547985330, COSV55409880; called by muse, mutect2, varscan2
- COG7 | c.436-1G>T p.X146_splice | Splice Site (SNP) | VAF 18/260 reads (7%) | catalogued as COSV56153673; called by muse, mutect2
- COL11A2 | c.3041C>T p.A1014V (on ENST00000341947 / NM_080680.3; = p.A907V on NM_080679.2) | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.746); catalogued as COSV59503411; called by muse, mutect2, varscan2
- COQ8B | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.455); catalogued as rs201827222, COSV54685871; called by muse, mutect2, varscan2
- CTNNBL1 | c.1517C>T p.A506V | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV63747679; called by muse, mutect2, varscan2
- CUBN | c.137C>T p.T46I | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV64702080; called by muse, mutect2, varscan2
- CX3CL1 | c.1153del p.R385Gfs*44 | Frame Shift Del (DEL) | VAF 26/74 reads (35%) | catalogued as COSV50057101; called by mutect2, pindel, varscan2
- CYB5R4 | c.741del p.E248Rfs*12 | Frame Shift Del (DEL) | VAF 145/169 reads (86%) | catalogued as rs745836350; called by mutect2, varscan2
- CYP4F2 | c.1180C>A p.P394T | Missense Mutation (SNP) | VAF 85/201 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55616497, COSV55622212; called by muse, mutect2, varscan2
- CZIB | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 90/212 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as COSV53760580; called by muse, mutect2
- DCAF11 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as rs781157092, COSV58110968; called by muse, mutect2, varscan2
- DCAF5 | c.2542G>A p.G848R | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.871); catalogued as rs772864002, COSV100432326, COSV58461605; called by muse, mutect2, varscan2
- DCAF8 | c.449C>A p.P150H | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.346); catalogued as COSV58786441; called by muse, mutect2, varscan2
- DDX46 | c.1895C>T p.A632V | Missense Mutation (SNP) | VAF 69/158 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV62801282; called by muse, mutect2, varscan2
- DENND4A | c.5558A>G p.E1853G | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.996); catalogued as COSV71267154; called by muse, mutect2, varscan2
- DHX29 | c.3806G>T p.G1269V | Missense Mutation (SNP) | VAF 55/208 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV52422902; called by muse, mutect2, varscan2
- DIP2C | c.1934A>G p.Q645R | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV55181855; called by muse, mutect2, varscan2
- DLEC1 | c.3443+2T>C p.X1148_splice | Splice Site (SNP) | VAF 46/89 reads (52%) | catalogued as COSV57307709; called by muse, mutect2, varscan2
- DNAH10 | c.4120C>T p.R1374C (on ENST00000409039; = p.R1313C on NM_207437.3) | Missense Mutation (SNP) | VAF 123/262 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs759236507, COSV69003767; called by muse, mutect2, varscan2
- DNAH7 | c.3203T>C p.F1068S | Missense Mutation (SNP) | VAF 70/156 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56789981; called by muse, mutect2, varscan2
- DNAJB1 | c.600A>T p.E200D | Missense Mutation (SNP) | VAF 72/166 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV54318362; called by muse, mutect2, varscan2
- DNASE2B | c.540G>T p.E180D | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.085); catalogued as COSV65738113; called by muse, mutect2, varscan2
- DYRK1A | c.983G>T p.R328L | Missense Mutation (SNP) | VAF 139/346 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58296748, COSV58297519; called by muse, varscan2
- EEF1AKMT4-ECE2 | c.1357C>T p.Q453* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as COSV62571327; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.287G>T p.R96L | Missense Mutation (SNP) | VAF 65/155 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV57518463; called by muse, mutect2, varscan2
- ENPP7 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.97); PolyPhen benign (0.005); catalogued as rs369080546; called by muse, mutect2, varscan2
- EP300 | c.3560G>A p.R1187H | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1289132149, COSV54346988; called by muse, mutect2, varscan2
- EPB41 | c.1744del p.T582Qfs*11 (on ENST00000343067 / NM_001166005.2; = p.T373Qfs*11 on NM_004437.4) | Frame Shift Del (DEL) | VAF 18/100 reads (18%) | catalogued as COSV58042400; called by mutect2, pindel, varscan2
- EPSTI1 | c.286G>C p.E96Q | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.04); catalogued as COSV58049408; called by muse, mutect2, varscan2
- ERCC4 | c.2474C>T p.A825V | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs765253522, COSV61314181; called by muse, mutect2, varscan2
- ERICH3 | c.1247A>G p.K416R | Missense Mutation (SNP) | VAF 142/319 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV58620605; called by muse, mutect2, varscan2
- F2 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.246); catalogued as rs762892196, COSV61315639; called by muse, mutect2, varscan2
- FA2H | c.1016A>G p.H339R | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54728393; called by muse, mutect2, varscan2
- FAM135A | c.2996del p.N999Ifs*5 (on ENST00000370479 / NM_001351599.1; = p.N786Ifs*5 on NM_020819.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 54/142 reads (38%) | catalogued as rs780725577; called by mutect2, varscan2
- FAM135B | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT tolerated (0.38); PolyPhen benign (0.065); catalogued as rs369404911, COSV50523175; called by muse, mutect2, varscan2
- FAM161A | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as rs1317325375, COSV56769077; called by muse, mutect2, varscan2
- FAM189B | c.1084G>A p.V362I | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as rs1553221053, COSV63220104; called by muse, mutect2, varscan2
- FANCM | c.4005del p.V1336Lfs*2 | Frame Shift Del (DEL) | VAF 21/124 reads (17%) | catalogued as rs746983128; called by mutect2, varscan2
- FAT1 | c.7846G>A p.V2616I | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs371619837, COSV71676247; called by muse, mutect2, varscan2
- FAT4 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV67902190; called by muse, mutect2, varscan2
- FBN3 | c.2284G>T p.E762* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | catalogued as COSV54474799; called by muse, mutect2, varscan2
- FERD3L | c.220G>A p.G74R | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as rs762869329, COSV51764610; called by muse, mutect2, varscan2
- FKBP9 | c.384del p.N129Ifs*10 | Frame Shift Del (DEL) | VAF 54/108 reads (50%) | catalogued as rs752076602; called by mutect2, varscan2
- FLRT2 | c.1646del p.G549Afs*3 | Frame Shift Del (DEL) | VAF 23/87 reads (26%) | catalogued as COSV58139763; called by mutect2, pindel, varscan2
- FRMD4A | c.1420C>A p.Q474K | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV52737772; called by muse, mutect2, varscan2
- FRYL | c.4784G>T p.R1595M | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51940773; called by muse, mutect2, varscan2
- FZD9 | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.62); PolyPhen benign (0.079); catalogued as COSV60671618; called by muse, mutect2, varscan2
- GAS6 | c.449del p.G150Afs*49 | Frame Shift Del (DEL) | VAF 16/32 reads (50%) | catalogued as rs773341392; called by mutect2, pindel, varscan2
- GAS8 | c.1310C>T p.T437M | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs145191565; called by muse, mutect2, varscan2
- GCKR | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as COSV53022671; called by muse, mutect2, varscan2
- GLYATL1 | c.820C>T p.R274C (on ENST00000317391 / NM_001354699.1; = p.R305C on NM_080661.4) | Missense Mutation (SNP) | VAF 95/217 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.589); catalogued as rs140092025, COSV55607610; called by muse, mutect2, varscan2
- GMCL1 | c.1297C>T p.R433C | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs1393894206, COSV57003606; called by muse, mutect2, varscan2
- GP1BA | c.1720G>A p.A574T | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0.04); catalogued as rs777415385, COSV56699781; called by muse, mutect2, varscan2
- GPAM | c.231A>T p.K77N | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV62082863; called by muse, mutect2, varscan2
- GPAT4 | c.1128G>T p.M376I | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV67842089; called by muse, mutect2, varscan2
- GPR50 | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 121/310 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as COSV54443548, COSV99505822; called by muse, mutect2, varscan2
- GPR87 | c.572A>G p.D191G | Missense Mutation (SNP) | VAF 66/266 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as rs1283106321, COSV53464770; called by muse, mutect2, varscan2
- GRIN2B | c.1271C>A p.P424H | Missense Mutation (SNP) | VAF 59/140 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV74205320, COSV74208281; called by muse, mutect2, varscan2
- GTF2H1 | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 72/192 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs532572506, COSV56377318; called by muse, mutect2, varscan2
- GTF3C1 | c.6068G>A p.R2023H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1040575243, COSV62245537; called by muse, mutect2, varscan2
- GTF3C1 | c.1178T>C p.M393T | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV62245542; called by muse, mutect2, varscan2
- GTF3C2 | c.2690G>A p.R897Q | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs374655370, COSV99272749; called by muse, mutect2, varscan2
- GUCY1B1 | c.1615C>T p.R539* | Nonsense Mutation (SNP) | VAF 57/144 reads (40%) | catalogued as rs761108028, COSV52374530; called by muse, mutect2, varscan2
- HAS1 | c.1024C>A p.L342I | Missense Mutation (SNP) | VAF 79/208 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs750817116, COSV55790054; called by muse, mutect2, varscan2
- HAUS5 | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs200911311, COSV52550226; called by muse, mutect2, varscan2
- HIRA | c.1225C>T p.Q409* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as COSV54273281; called by muse, mutect2, varscan2
- HK3 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs563509390, COSV52845375; called by muse, mutect2, varscan2
- HOATZ | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 78/179 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.025); catalogued as COSV60442697, COSV60442856; called by muse, mutect2, varscan2
- HPSE2 | c.776T>G p.L259R | Missense Mutation (SNP) | VAF 70/161 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65203555; called by muse, mutect2, varscan2
- HSPG2 | c.3748G>A p.A1250T | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as rs779841547, COSV65973965; called by muse, mutect2
- HTR1F | c.70del p.I24Ffs*12 | Frame Shift Del (DEL) | VAF 114/307 reads (37%) | catalogued as rs1393441207; called by mutect2, pindel, varscan2
- ID1 | c.350C>T p.T117I | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as rs756315343, COSV65888960; called by muse, mutect2
- IFI44L | c.319del p.I107Lfs*26 | Frame Shift Del (DEL) | VAF 28/80 reads (35%) | catalogued as rs1557683804; called by mutect2, pindel, varscan2
- IGF2R | c.5662G>A p.V1888M | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.035); catalogued as rs374125303, COSV63629512; called by muse, mutect2, varscan2
- ILK | c.211del p.L71Cfs*26 | Frame Shift Del (DEL) | VAF 18/47 reads (38%) | catalogued as rs776120061, COSV54448886; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- INTS6L | c.359del p.L120* | Frame Shift Del (DEL) | VAF 60/117 reads (51%) | catalogued as rs782242788; ClinVar: uncertain significance; called by mutect2, varscan2
- IQSEC1 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs549147535, COSV56227371; called by muse, mutect2, varscan2
- IQSEC2 | c.1045A>G p.R349G (on ENST00000642864 / NM_001111125.3; = p.R144G on NM_015075.2) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV64728498; called by muse, mutect2, varscan2
- ITGA6 | c.1879A>G p.I627V (on ENST00000442250; = p.I588V on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as rs1248871018, COSV51280964; called by muse, mutect2, varscan2
- ITGAM | c.878G>A p.S293N | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV54943562; called by muse, mutect2, varscan2
- JHY | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1364181517, COSV56218864; called by muse, mutect2, varscan2
- KCNT1 | c.3426G>T p.E1142D (on ENST00000488444; = p.E1123D on NM_001272003.2) | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (0.52); PolyPhen benign (0.053); catalogued as COSV53712436; called by muse, mutect2, varscan2
- KCNV2 | c.1094C>T p.T365M | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs547033951, COSV66057050; called by muse, mutect2, varscan2
- KDF1 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.528); catalogued as rs770558931, COSV57671923; called by muse, mutect2
- KIF26B | c.6095G>A p.R2032H | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs774064902, COSV63653739; called by muse, mutect2, varscan2
- KIFC3 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as rs200757236; called by muse, mutect2, varscan2
- KLF3 | c.677del p.P226Rfs*52 | Frame Shift Del (DEL) | VAF 108/297 reads (36%) | catalogued as COSV54711577; called by mutect2, pindel, varscan2
- KLHL10 | c.764G>A p.C255Y | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53175333; called by muse, mutect2, varscan2
- KMT2B | c.5265del p.I1756Lfs*139 | Frame Shift Del (DEL) | VAF 37/97 reads (38%) | catalogued as COSV55869715; called by mutect2, pindel, varscan2
- KMT2D | c.6214C>A p.R2072S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56492714; called by muse, mutect2, varscan2
- KNOP1 | c.652del p.I218Sfs*41 | Frame Shift Del (DEL) | VAF 21/38 reads (55%) | catalogued as rs764099275; called by mutect2, varscan2
- KSR2 | c.1606del p.L536Sfs*61 | Frame Shift Del (DEL) | VAF 15/39 reads (38%) | catalogued as rs770565486; called by mutect2, pindel, varscan2
- LAMA3 | c.4631G>A p.G1544D | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58082582; called by muse, mutect2, varscan2
- LANCL2 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.247); catalogued as COSV54653170; called by muse, mutect2, varscan2
- LARP1 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs1183655887, COSV60431810, COSV60431973; called by muse, mutect2, varscan2
- LGR5 | c.2516A>G p.Y839C | Missense Mutation (SNP) | VAF 119/252 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV57010728; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 112/282 reads (40%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LMNA | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.373); catalogued as rs1024051591, COSV61544164; called by muse, mutect2, varscan2
- LONRF1 | c.1246G>A p.V416I | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV68038104; called by muse, mutect2, varscan2
- LRP5 | c.2104G>A p.A702T | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771775019, COSV53720884; called by muse, mutect2, varscan2
- LRRC8C | c.1524del p.W509Gfs*13 | Frame Shift Del (DEL) | VAF 67/192 reads (35%) | catalogued as rs762972819; called by mutect2, pindel, varscan2
- LSR | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.195); catalogued as rs373575043; called by muse, mutect2
- LURAP1L | c.497G>A p.S166N | Missense Mutation (SNP) | VAF 113/273 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59986611; called by muse, mutect2, varscan2
- MAP1S | c.3127A>C p.S1043R | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60724903; called by muse, mutect2, varscan2
- MBNL2 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 89/211 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as rs1357311025, COSV59121241; called by muse, mutect2, varscan2
- MCF2 | c.780dup p.L261Ifs*6 | Frame Shift Ins (INS) | VAF 13/79 reads (16%) | catalogued as rs1440858020; called by mutect2, varscan2
- MED13L | c.2909G>A p.C970Y | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56131822; called by muse, mutect2, varscan2
- MFAP3L | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs986071436, COSV64371920; called by muse, mutect2, varscan2
- MICB | c.779G>T p.G260V | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.788); catalogued as COSV52858093; called by muse, mutect2, varscan2
- MINDY3 | c.313T>C p.Y105H | Missense Mutation (SNP) | VAF 80/172 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as COSV53224959; called by muse, mutect2, varscan2
- MMS22L | c.2799del p.V934Ffs*8 | Frame Shift Del (DEL) | VAF 88/236 reads (37%) | catalogued as rs1562416103; called by mutect2, pindel, varscan2
- MSANTD3 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as rs750365142, COSV58497997; called by muse, mutect2, varscan2
- MST1R | c.2668G>A p.V890M | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56574852; called by muse, mutect2, varscan2
- MTG2 | c.941A>G p.Q314R | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV63695050; called by muse, mutect2, varscan2
- MTMR2 | c.1232C>T p.T411M | Missense Mutation (SNP) | VAF 88/182 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.874); catalogued as rs1160054714, COSV60582404; called by muse, mutect2, varscan2
- MUC5B | c.7486G>C p.V2496L | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV71596411; called by muse, mutect2, varscan2
- MUC6 | c.4025C>T p.T1342M | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.12); catalogued as rs779884281, COSV70141437; called by muse, mutect2
- MYH14 | c.5330G>A p.R1777H | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs774682178, COSV51833371; called by muse, mutect2, varscan2
- MYO1A | c.2584C>T p.P862S | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.102); catalogued as COSV55654067; called by muse, mutect2, varscan2
- NAA11 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 73/164 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1475502851, COSV54516272; called by muse, mutect2, varscan2
- NAF1 | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1040664045, COSV56803889; called by muse, mutect2, varscan2
- NARS1 | c.323G>C p.S108T | Missense Mutation (SNP) | VAF 64/168 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs777515260, COSV56878488; called by muse, mutect2, varscan2
- NCAPG2 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 49/89 reads (55%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.985); catalogued as rs756707913, COSV51992398; called by muse, mutect2, varscan2
- NEO1 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 111/249 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0.038); catalogued as COSV56079016; called by muse, mutect2, varscan2
- NFE2L2 | c.479A>G p.N160S | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs751483512, COSV67962783; called by muse, mutect2, varscan2
- NFIX | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1204135009, COSV62175646; called by muse, mutect2, varscan2
- NOS1AP | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.225); catalogued as COSV62633857, COSV62640354; called by muse, mutect2, varscan2
- NOTCH4 | c.3824C>T p.A1275V | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.219); catalogued as COSV66684420; called by muse, mutect2, varscan2
- NPHS1 | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.655); catalogued as COSV62287153, COSV62290133; called by muse, mutect2, varscan2
- NR2C2 | c.1689del p.F563Lfs*10 (on ENST00000393102; = p.F582Lfs*10 on NM_003298.5) | Frame Shift Del (DEL) | VAF 29/66 reads (44%) | catalogued as rs774343392; called by mutect2, varscan2
- NR4A2 | c.955C>T p.R319* | Nonsense Mutation (SNP) | VAF 22/61 reads (36%) | catalogued as COSV100277014, COSV59895944; called by muse, mutect2, varscan2
- NRG3 | c.1478G>T p.R493M | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64587430; called by muse, mutect2, varscan2
- NRXN3 | c.1561C>T p.L521F (on ENST00000335750 / NM_001330195.2; = p.L148F on NM_004796.6) | Missense Mutation (SNP) | VAF 76/203 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs1326966067, COSV59814485; called by muse, mutect2, varscan2
- NUMB | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 52/128 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV61832539; called by muse, mutect2, varscan2
- OR4K14 | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 78/191 reads (41%) | SIFT tolerated (0.78); PolyPhen benign (0.006); catalogued as rs751709937, COSV59292230; called by muse, mutect2, varscan2
- OR51E2 | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 72/169 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV67808954; called by muse, mutect2, varscan2
- OR6N2 | c.857A>G p.N286S | Missense Mutation (SNP) | VAF 225/474 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1255115408, COSV59413458; called by muse, mutect2, varscan2
- OR8B8 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 131/335 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV60144537, COSV60145976; called by muse, mutect2, varscan2
- PAN2 | c.515G>A p.G172D | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57756446; called by muse, mutect2, varscan2
- PANX1 | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 73/178 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1047423158, COSV57135328; called by muse, mutect2, varscan2
- PARP14 | c.5092A>G p.N1698D | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV71735681; called by muse, mutect2, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 27/67 reads (40%) | catalogued as CM011452; called by mutect2, pindel
- PCDH15 | c.5113G>T p.E1705* | Nonsense Mutation (SNP) | VAF 19/36 reads (53%) | catalogued as COSV64739735; called by muse, mutect2, varscan2
- PCDHA10 | c.1339G>A p.V447M | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.792); catalogued as rs369919324, COSV56513995; called by muse, mutect2
- PCDHA2 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.361); catalogued as COSV65365111; called by muse, mutect2, varscan2
- PCDHGB1 | c.779G>T p.R260L | Missense Mutation (SNP) | VAF 89/195 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.088); catalogued as COSV54048141; called by muse, mutect2, varscan2
- PCSK7 | c.1045G>A p.V349I | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.503); catalogued as rs372878339; called by muse, mutect2, varscan2
- PDCD2 | c.752A>G p.E251G | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV51340994, COSV51341541; called by muse, mutect2, varscan2
- PFKP | c.1277A>G p.N426S | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66902100; called by muse, mutect2, varscan2
- PGBD2 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs146329960; called by muse, mutect2, varscan2
- PHIP | c.1642A>G p.K548E | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.152); catalogued as COSV51511819; called by muse, mutect2, varscan2
- PHLDB2 | c.1343A>G p.Q448R | Missense Mutation (SNP) | VAF 103/539 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs774585872, COSV67316648; called by muse, mutect2, varscan2
- PIKFYVE | c.5183G>A p.R1728H | Missense Mutation (SNP) | VAF 73/162 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as rs371097164; called by muse, mutect2, varscan2
- PKD1L1 | c.1071dup p.H358Sfs*30 | Frame Shift Ins (INS) | VAF 28/146 reads (19%) | catalogued as rs544774439; called by mutect2, varscan2
- PRDM2 | c.2809A>G p.T937A | Missense Mutation (SNP) | VAF 142/332 reads (43%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1316533068, COSV52456905; called by muse, mutect2, varscan2
- PROX1 | c.1645G>T p.G549W | Missense Mutation (SNP) | VAF 112/243 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as COSV54784505; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1843C>T p.Q615* (on ENST00000352766; = p.Q536* on NM_181334.5) | Nonsense Mutation (SNP) | VAF 14/28 reads (50%) | catalogued as rs761837941, COSV61237440; called by muse, mutect2
- PSMD3 | c.1476G>T p.K492N | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52860102; called by muse, mutect2, varscan2
- PSME4 | c.4919C>A p.P1640H | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV66368262; called by muse, mutect2, varscan2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 130/282 reads (46%) | catalogued as rs146650273; called by pindel, varscan2
- QRFP | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs758232110, COSV58064825; called by muse, mutect2
- RAD54L2 | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.195); catalogued as rs754436021, COSV56582014; called by muse, mutect2, varscan2
- RAE1 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 122/283 reads (43%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.769); catalogued as rs1384868563, COSV64798620; called by muse, mutect2, varscan2
- RASA3 | c.122A>G p.N41S | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.98); PolyPhen benign (0.214); catalogued as COSV61874491; called by muse, mutect2, varscan2
- REEP1 | c.417G>T p.K139N | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as COSV51260035; called by muse, mutect2, varscan2
- RFC5 | c.664A>T p.S222C | Missense Mutation (SNP) | VAF 110/209 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57478999; called by muse, mutect2, varscan2
- RIMS4 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 73/176 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV65719751; called by muse, varscan2
- RNF5 | c.409G>A p.V137I | Missense Mutation (SNP) | VAF 111/235 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.034); catalogued as rs750217083, COSV61248139; called by muse, mutect2, varscan2
- ROCK1 | c.3921del p.K1307Nfs*3 | Frame Shift Del (DEL) | VAF 16/127 reads (13%) | catalogued as rs752898741; called by mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 28/58 reads (48%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPS6KA1 | c.1104del p.S369Afs*18 | Frame Shift Del (DEL) | VAF 8/21 reads (38%) | catalogued as rs745561139; called by mutect2, pindel, varscan2
- RPS6KC1 | c.1666G>A p.A556T | Missense Mutation (SNP) | VAF 74/160 reads (46%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV65303183; called by muse, mutect2, varscan2
- RRAGA | c.390T>A p.D130E | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65844261; called by muse, mutect2, varscan2
- RRAS | c.173A>G p.Y58C | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55869209; called by muse, mutect2, varscan2
- RTL9 | c.3559G>A p.A1187T | Missense Mutation (SNP) | VAF 10/297 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs932791429, COSV71826545; called by muse, mutect2
- RYR1 | c.7726G>A p.A2576T | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.658); catalogued as rs767394054, COSV62089628; called by muse, mutect2, varscan2
- RYR3 | c.14125G>A p.D4709N (on ENST00000389232; = p.D4710N on NM_001036.6) | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.544); catalogued as rs431825174, COSV66776875; ClinVar: not provided; called by muse, mutect2, varscan2
- SCAPER | c.2236del p.I746Ffs*26 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | catalogued as rs1462082548; called by mutect2, varscan2
- SDK1 | c.1219G>A p.G407R | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as rs780085119, COSV67391027; called by muse, varscan2
- SDK1 | c.1550A>G p.N517S | Missense Mutation (SNP) | VAF 112/279 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV67391031; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 32/56 reads (57%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEMA4F | c.2062C>T p.R688* | Nonsense Mutation (SNP) | VAF 34/73 reads (47%) | catalogued as rs576653391, COSV60285573; called by muse, mutect2, varscan2
- SEMA6A | c.2008G>A p.V670I | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1307671471, COSV56715487; called by muse, mutect2, varscan2
- SERAC1 | c.576del p.L193Sfs*9 | Frame Shift Del (DEL) | VAF 56/162 reads (35%) | catalogued as CD125519, COSV65598313; called by mutect2, pindel, varscan2
- SGO2 | c.1943del p.F648Sfs*14 | Frame Shift Del (DEL) | VAF 111/240 reads (46%) | catalogued as rs771387868; called by mutect2, varscan2
- SHPRH | c.495del p.E166Nfs*3 | Frame Shift Del (DEL) | VAF 85/188 reads (45%) | catalogued as rs1469942319; called by mutect2, varscan2
- SHQ1 | c.1693A>G p.N565D | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.003); catalogued as COSV57768748; called by muse, mutect2, varscan2
- SIN3B | c.569_582+12del p.X190_splice | Splice Site (DEL) | VAF 31/103 reads (30%) | catalogued as COSV56136962; called by mutect2, pindel, varscan2
- SIPA1L1 | c.2224C>T p.H742Y | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV62174297; called by muse, mutect2, varscan2
- SLC11A2 | c.1633G>A p.V545M (on ENST00000394904 / NM_001379455.1; = p.V516M on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/163 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.742); catalogued as rs372439379; called by muse, mutect2, varscan2
- SLC12A4 | c.1307C>T p.A436V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV57936472; called by muse, mutect2, varscan2
- SLC30A8 | c.971G>A p.S324N | Missense Mutation (SNP) | VAF 90/197 reads (46%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV69977002; called by muse, mutect2, varscan2
- SLCO1C1 | c.1233del p.I412* | Frame Shift Del (DEL) | VAF 54/181 reads (30%) | catalogued as rs766878114, COSV56867969; called by mutect2, pindel, varscan2
- SLCO2B1 | c.875T>C p.I292T | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV56940170; called by muse, mutect2, varscan2
- SLCO6A1 | c.1465T>C p.Y489H | Missense Mutation (SNP) | VAF 86/179 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65815484; called by muse, mutect2, varscan2
- SMAP1 | c.613del p.S205Vfs*15 (on ENST00000370455 / NM_001044305.3; = p.S178Vfs*15 on NM_021940.5) | Frame Shift Del (DEL) | VAF 13/45 reads (29%) | catalogued as rs766085867, COSV100391091; called by mutect2, varscan2
- SNAP25 | c.131T>C p.I44T | Missense Mutation (SNP) | VAF 59/118 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV54776508; called by muse, mutect2, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 60/130 reads (46%) | catalogued as rs768873484; called by mutect2, varscan2
- SPAG16 | c.674C>A p.P225Q | Missense Mutation (SNP) | VAF 17/246 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV55983306, COSV55987220; called by muse, mutect2
- SPATA2 | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs900677334, COSV56865369; called by muse, mutect2, varscan2
- SPTB | c.2831C>T p.S944L | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs778518876, COSV67635596; called by muse, mutect2, varscan2
- SRBD1 | c.1370G>A p.G457E | Missense Mutation (SNP) | VAF 73/161 reads (45%) | SIFT tolerated (0.9); PolyPhen benign (0.138); catalogued as COSV55406482; called by muse, mutect2, varscan2
- SRRM1 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs762320650, COSV60481118; called by muse, mutect2, varscan2
- ST6GAL2 | c.1155dup p.P386Tfs*27 | Frame Shift Ins (INS) | VAF 54/144 reads (38%) | catalogued as rs1261813632; called by mutect2, pindel, varscan2
- STEAP3 | c.1321G>A p.V441I | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs771999099, COSV61529103; called by muse, mutect2, varscan2
- STRA6 | c.989C>T p.T330I | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV60589031; called by muse, mutect2, varscan2
- STRADA | c.195G>T p.E65D (on ENST00000336174 / NM_001363786.1; = p.E28D on NM_153335.6) | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55564847; called by muse, mutect2, varscan2
- SVEP1 | c.6434G>A p.R2145Q | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs750478793, COSV52844824; called by muse, mutect2, varscan2
- SYN3 | c.926C>A p.S309Y | Missense Mutation (SNP) | VAF 63/131 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60503599, COSV60517781; called by muse, mutect2, varscan2
- SYNE3 | c.1912-1G>T p.X638_splice | Splice Site (SNP) | VAF 23/53 reads (43%) | catalogued as COSV62083215; called by muse, mutect2
- SYNPO | c.2401C>T p.P801S (on ENST00000394243 / NM_001166208.2; = p.P557S on NM_007286.6) | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.57); catalogued as COSV56943705; called by muse, mutect2, varscan2
- TAF1L | c.5087C>A p.S1696Y | Missense Mutation (SNP) | VAF 157/370 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1489437859, COSV54271246; called by muse, mutect2, varscan2
- TAF6 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59844331; called by muse, mutect2, varscan2
- TAOK3 | c.295-1G>C p.X99_splice | Splice Site (SNP) | VAF 18/44 reads (41%) | catalogued as COSV66828284; called by muse, mutect2, varscan2
- TARDBP | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as COSV53569786; called by muse, mutect2, varscan2
- TASOR2 | c.4243C>T p.R1415* | Nonsense Mutation (SNP) | VAF 86/198 reads (43%) | catalogued as COSV60169291; called by muse, mutect2, varscan2
- TCHH | c.3108G>T p.E1036D | Missense Mutation (SNP) | VAF 186/466 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.129); catalogued as COSV64278193; called by muse, mutect2, varscan2
- TEP1 | c.6643G>A p.G2215R | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766727831, COSV52989620; called by muse, mutect2, varscan2
- TEP1 | c.3563C>A p.P1188H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.876); catalogued as COSV53001540, COSV99403525; called by muse, mutect2
- TEX55 | c.1421A>G p.Q474R | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV55213134; called by muse, mutect2
- TGOLN2 | c.491G>A p.S164N | Missense Mutation (SNP) | VAF 211/461 reads (46%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.961); catalogued as COSV56407789; called by muse, mutect2, varscan2
- THOC2 | c.1070A>G p.D357G | Missense Mutation (SNP) | VAF 164/395 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.143); catalogued as COSV55556940; called by muse, mutect2, varscan2
- TJP2 | c.342T>G p.I114M | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55275331; called by muse, mutect2, varscan2
- TMCO1 | c.451G>A p.A151T (on ENST00000612311 / NM_001256164.1; = p.A100T on NM_019026.6) | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.056); catalogued as COSV63319288; called by muse, varscan2
- TMEM161A | c.802T>C p.F268L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50778234; called by muse, mutect2, varscan2
- TMEM231 | c.574C>T p.R192* (on ENST00000258173 / NM_001077418.3; = p.R221* on NM_001077416.2) | Nonsense Mutation (SNP) | VAF 68/197 reads (35%) | catalogued as rs543122080, COSV50738913, COSV50739882; ClinVar: uncertain significance; called by muse, mutect2
- TP53BP1 | c.1531del p.D511Ifs*5 | Frame Shift Del (DEL) | VAF 18/70 reads (26%) | catalogued as COSV99781767; called by mutect2, pindel, varscan2
- TRAV9-2 | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 25/234 reads (11%) | catalogued as rs1408315620; called by muse, mutect2, varscan2
- TRIM26 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0.301); catalogued as rs144770536; called by muse, mutect2, varscan2
- TRIM67 | c.2174T>C p.L725P | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV64160898; called by muse, mutect2, varscan2
- TRMT1 | c.1789C>T p.R597W | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as rs201873417, COSV53400617; called by muse, mutect2, varscan2
- TRMT61B | c.556del p.A186Qfs*16 | Frame Shift Del (DEL) | VAF 100/260 reads (38%) | catalogued as rs746516437; called by mutect2, pindel, varscan2
- TRPC1 | c.1545del p.F515Lfs*41 (on ENST00000476941 / NM_001251845.2; = p.F481Lfs*41 on NM_003304.4) | Frame Shift Del (DEL) | VAF 90/235 reads (38%) | catalogued as rs1214691323, COSV99858337; called by mutect2, pindel, varscan2
- TRPC3 | c.370A>G p.N124D (on ENST00000379645 / NM_001366479.2; = p.N51D on NM_003305.2) | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.791); catalogued as COSV53382526; called by muse, mutect2, varscan2
- TSHZ3 | c.691G>A p.V231M | Missense Mutation (SNP) | VAF 117/238 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53684787; called by muse, mutect2, varscan2
- TSPOAP1 | c.4252C>T p.R1418C | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as rs774849443, COSV52119258; called by muse, mutect2, varscan2
- TSPYL2 | c.1561A>G p.N521D | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.636); catalogued as rs1556808508, COSV64921599; called by muse, mutect2, varscan2
- TTC3 | c.2334del p.E779Kfs*5 | Frame Shift Del (DEL) | VAF 102/230 reads (44%) | catalogued as rs756650873; called by mutect2, varscan2
- TTC7A | c.1229C>T p.A410V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs771992889, COSV55413186; called by muse, mutect2, varscan2
- TTN | c.29255C>T p.A9752V (on ENST00000591111; = p.A8825V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 111/271 reads (41%) | PolyPhen possibly damaging (0.475); catalogued as COSV60019911, COSV60391943; called by muse, mutect2, varscan2
- TUBE1 | c.334G>A p.G112S | Missense Mutation (SNP) | VAF 61/126 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64088186; called by muse, mutect2, varscan2
- TXNDC5 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs758889890, COSV65731131; called by muse, mutect2, varscan2
- UBE2E1 | c.336G>A p.K112= | Splice Region (SNP) | VAF 52/127 reads (41%) | catalogued as COSV60670118; called by muse, mutect2, varscan2
- UBR2 | c.3161G>A p.R1054Q | Missense Mutation (SNP) | VAF 66/149 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as rs773272485, COSV65748781; called by muse, mutect2, varscan2
- UGDH | c.214del p.S72Lfs*18 | Frame Shift Del (DEL) | VAF 48/122 reads (39%) | catalogued as rs765734647, COSV57097233; called by mutect2, varscan2
- UNG | c.805C>T p.R269W (on ENST00000242576 / NM_080911.3; = p.R260W on NM_003362.4) | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs143034537; called by muse, mutect2, varscan2
- UROC1 | c.920del p.K307Rfs*77 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | catalogued as rs754361807; called by mutect2, varscan2
- USP35 | c.2587T>C p.Y863H | Missense Mutation (SNP) | VAF 64/197 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60871522; called by muse, mutect2, varscan2
- USP39 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 67/152 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60383923; called by muse, mutect2, varscan2
- VPS33A | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 72/182 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.168); catalogued as rs1247451944, COSV57356352; called by muse, mutect2, varscan2
- WDFY2 | c.979T>C p.S327P | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as COSV53293490; called by muse, mutect2, varscan2
- WDR35 | c.964G>A p.V322I | Missense Mutation (SNP) | VAF 53/106 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as rs753983503, COSV55607634; called by muse, mutect2, varscan2
- WDR36 | c.1637C>T p.A546V | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.434); catalogued as COSV72605533; called by muse, mutect2, varscan2
- WDR37 | c.1381G>A p.A461T | Missense Mutation (SNP) | VAF 43/83 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV54132024; called by muse, mutect2, varscan2
- WDR64 | c.949G>A p.V317I | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.762); catalogued as COSV63801185; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 18/46 reads (39%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WFDC1 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as rs145066295; called by muse, mutect2, varscan2
- WIPF2 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV60276292; called by muse, mutect2, varscan2
- WNT16 | c.500del p.G167Afs*17 (on ENST00000222462 / NM_057168.2; = p.G157Afs*17 on NM_016087.2) | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | catalogued as rs771899177; called by mutect2, pindel
- XPOT | c.378del p.F126Lfs*6 | Frame Shift Del (DEL) | VAF 54/106 reads (51%) | catalogued as rs762052135; called by mutect2, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | catalogued as rs779864368; called by mutect2, pindel
- ZCCHC9 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs748879820, COSV54176085; called by muse, mutect2, varscan2
- ZDBF2 | c.5184del p.K1728Nfs*5 | Frame Shift Del (DEL) | VAF 50/114 reads (44%) | catalogued as rs745875253; called by mutect2, varscan2
- ZDBF2 | c.6878G>A p.R2293Q | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768713455, COSV65621358, COSV65630133; called by muse, mutect2, varscan2
- ZKSCAN5 | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 145/311 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1436241073, COSV58744853; called by muse, mutect2, varscan2
- ZNF347 | c.1664G>A p.S555N | Missense Mutation (SNP) | VAF 207/442 reads (47%) | SIFT tolerated (0.81); PolyPhen benign (0.026); catalogued as rs758409692, COSV61971282; called by muse, mutect2, varscan2
- ZNF391 | c.92C>A p.P31H | Missense Mutation (SNP) | VAF 130/308 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV55125266; called by muse, mutect2, varscan2
- ZNF560 | c.2263C>T p.R755C | Missense Mutation (SNP) | VAF 97/219 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as rs377042499; called by muse, mutect2, varscan2
- ZNF629 | c.647G>A p.S216N | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.716); catalogued as COSV52700978; called by muse, mutect2, varscan2
- ZNF839 | c.575T>G p.L192R (on ENST00000558850 / NM_001267827.1; = p.L308R on NM_018335.5) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51759946; called by muse, mutect2, varscan2
- ZNFX1 | c.3188A>G p.N1063S | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.473); catalogued as COSV65579878; called by muse, mutect2, varscan2
- ZNRF2 | c.704C>A p.S235Y | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV59912418; called by muse, mutect2, varscan2
- ZSCAN5B | c.179A>G p.Q60R | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.988); catalogued as COSV62841145; called by muse, mutect2, varscan2
- ABL1 | c.2352del p.R785Gfs*3 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | called by mutect2, pindel, varscan2
- AC242842.3 | c.1635del p.K545Nfs*78 | Frame Shift Del (DEL) | VAF 33/268 reads (12%) | called by mutect2, pindel, varscan2
- AL136295.1 | c.2398del p.S800Lfs*3 | Frame Shift Del (DEL) | VAF 16/97 reads (16%) | called by mutect2, varscan2
- ARHGAP30 | c.723del p.E242Rfs*43 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | called by mutect2, pindel, varscan2
- ARHGAP5 | c.2805del p.F935Lfs*5 | Frame Shift Del (DEL) | VAF 90/268 reads (34%) | called by mutect2, pindel, varscan2
- ARHGEF28 | c.1050del p.K350Nfs*18 | Frame Shift Del (DEL) | VAF 28/54 reads (52%) | called by mutect2, varscan2
- ARID1B | c.2426del p.G809Afs*23 | Frame Shift Del (DEL) | VAF 49/122 reads (40%) | called by mutect2, pindel, varscan2
- ARID4B | c.3753del p.K1251Nfs*4 | Frame Shift Del (DEL) | VAF 20/46 reads (43%) | called by mutect2, pindel, varscan2
- ARSF | c.1598del p.K533Rfs*6 | Frame Shift Del (DEL) | VAF 46/127 reads (36%) | called by mutect2, pindel, varscan2
- ASIC2 | c.636del p.T213Qfs*32 | Frame Shift Del (DEL) | VAF 28/136 reads (21%) | called by pindel, varscan2
- ASXL3 | c.2625del p.V876Cfs*59 | Frame Shift Del (DEL) | VAF 28/86 reads (33%) | called by mutect2, varscan2
- BCORL1 | c.3620del p.K1207Rfs*15 | Frame Shift Del (DEL) | VAF 42/105 reads (40%) | called by mutect2, pindel, varscan2
- BRD3 | c.1919del p.K640Sfs*21 | Frame Shift Del (DEL) | VAF 11/28 reads (39%) | called by mutect2, pindel, varscan2
- CCDC62 | c.1850dup p.A618Gfs*10 | Frame Shift Ins (INS) | VAF 58/165 reads (35%) | called by mutect2, pindel, varscan2
- CCT3 | c.591del p.K197Nfs*23 | Frame Shift Del (DEL) | VAF 105/250 reads (42%) | called by mutect2, pindel, varscan2
- CFAP70 | c.1695dup p.Y566Ifs*19 | Frame Shift Ins (INS) | VAF 55/145 reads (38%) | called by mutect2, pindel, varscan2
- CNOT10 | c.2039del p.P680Lfs*33 | Frame Shift Del (DEL) | VAF 36/85 reads (42%) | called by mutect2, pindel, varscan2
- CTCF | c.897_898del p.C299Wfs*15 | Frame Shift Del (DEL) | VAF 48/118 reads (41%) | called by pindel, varscan2
- DDX24 | c.528del p.A177Rfs*34 | Frame Shift Del (DEL) | VAF 84/172 reads (49%) | called by mutect2, pindel, varscan2
- DICER1 | c.5191del p.V1731Sfs*2 | Frame Shift Del (DEL) | VAF 60/147 reads (41%) | called by mutect2, pindel, varscan2
- DLGAP3 | c.1130del p.G377Vfs*91 | Frame Shift Del (DEL) | VAF 25/124 reads (20%) | called by mutect2, pindel, varscan2
- DNAJC18 | c.849dup p.D284* | Frame Shift Ins (INS) | VAF 86/201 reads (43%) | called by mutect2, pindel, varscan2
- DST | c.5686del p.I1896* | Frame Shift Del (DEL) | VAF 62/156 reads (40%) | called by mutect2, pindel, varscan2
- EIF4G3 | c.247del p.Q83Nfs*43 | Frame Shift Del (DEL) | VAF 13/34 reads (38%) | called by mutect2, pindel, varscan2
- EYA3 | c.842del p.N281Tfs*2 | Frame Shift Del (DEL) | VAF 90/213 reads (42%) | called by mutect2, pindel, varscan2
- FLNC | c.5187del p.F1730Sfs*53 | Frame Shift Del (DEL) | VAF 9/33 reads (27%) | called by mutect2, pindel, varscan2
- FRA10AC1 | c.694dup p.R232Kfs*4 | Frame Shift Ins (INS) | VAF 48/127 reads (38%) | called by mutect2, varscan2
- FREM1 | c.2541del p.V848Lfs*44 | Frame Shift Del (DEL) | VAF 8/80 reads (10%) | called by mutect2, pindel
- GLDC | c.1437dup p.D480Rfs*12 | Frame Shift Ins (INS) | VAF 37/89 reads (42%) | called by mutect2, pindel, varscan2
- GRK4 | c.668_671del p.I223Rfs*10 (on ENST00000398052 / NM_182982.3; = p.I191Rfs*10 on NM_005307.3) | Frame Shift Del (DEL) | VAF 106/257 reads (41%) | called by mutect2, pindel, varscan2
- GUCY2C | c.1080del p.F360Lfs*8 | Frame Shift Del (DEL) | VAF 92/251 reads (37%) | called by mutect2, pindel, varscan2
- HIVEP3 | c.3662del p.P1221Lfs*163 | Frame Shift Del (DEL) | VAF 14/39 reads (36%) | called by mutect2, pindel, varscan2
- HOOK3 | c.1637dup p.K547Efs*3 | Frame Shift Ins (INS) | VAF 47/114 reads (41%) | called by mutect2, pindel, varscan2
- IDI2 | c.585del p.W196Gfs*2 | Frame Shift Del (DEL) | VAF 26/81 reads (32%) | called by mutect2, pindel, varscan2
- IMPG2 | c.185del p.K62Rfs*15 | Frame Shift Del (DEL) | VAF 58/327 reads (18%) | called by mutect2, pindel, varscan2
- INO80E | c.318_319del p.P107Lfs*37 | Frame Shift Del (DEL) | VAF 11/24 reads (46%) | called by pindel, varscan2
- ITGAV | c.1682del p.G561Dfs*2 | Frame Shift Del (DEL) | VAF 269/416 reads (65%) | called by mutect2, pindel, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 130/147 reads (88%) | called by mutect2, varscan2
- KCNRG | c.470del p.F157Sfs*5 | Frame Shift Del (DEL) | VAF 24/210 reads (11%) | called by mutect2, pindel, varscan2
- MAP3K4 | c.531del p.K177Nfs*30 | Frame Shift Del (DEL) | VAF 68/194 reads (35%) | called by mutect2, pindel, varscan2
- MCM5 | c.199del p.E67Sfs*40 | Frame Shift Del (DEL) | VAF 52/100 reads (52%) | called by mutect2, varscan2
- MICAL2 | c.4194del p.K1399Rfs*36 | Frame Shift Del (DEL) | VAF 22/105 reads (21%) | called by mutect2, pindel, varscan2
- MTG1 | c.986del p.P329Rfs*28 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- MUC16 | c.30568_30570del p.P10190del | In Frame Del (DEL) | VAF 21/41 reads (51%) | called by mutect2, pindel, varscan2
- MUC4 | c.13227del p.T4410Pfs*17 (on ENST00000463781 / NM_018406.7; = p.T174Pfs*17 on NM_004532.6) | Frame Shift Del (DEL) | VAF 22/42 reads (52%) | called by mutect2, pindel, varscan2
- NEURL4 | c.3765del p.L1256Cfs*12 | Frame Shift Del (DEL) | VAF 11/29 reads (38%) | called by mutect2, pindel, varscan2
- NFAT5 | c.3182del p.L1061Cfs*87 | Frame Shift Del (DEL) | VAF 210/472 reads (44%) | called by mutect2, varscan2
- NOS2 | c.66del p.D23Tfs*17 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | called by mutect2, pindel, varscan2
- PCDHB14 | c.1237_1238del p.S413Pfs*30 | Frame Shift Del (DEL) | VAF 87/258 reads (34%) | called by pindel, varscan2
- PCOLCE2 | c.711-3del | Splice Region (DEL) | VAF 41/125 reads (33%) | called by mutect2, pindel, varscan2
- PDS5B | c.3585del p.S1198Vfs*10 | Frame Shift Del (DEL) | VAF 56/158 reads (35%) | called by mutect2, pindel, varscan2
- PHYHIPL | c.780del p.F260Lfs*22 | Frame Shift Del (DEL) | VAF 61/181 reads (34%) | called by mutect2, pindel, varscan2
- PLSCR3 | c.725del p.G242Afs*23 | Frame Shift Del (DEL) | VAF 10/55 reads (18%) | called by mutect2, pindel, varscan2
- PNISR | c.311dup p.P105Sfs*20 | Frame Shift Ins (INS) | VAF 42/82 reads (51%) | called by mutect2, varscan2
- POLE2 | c.783dup p.G262Wfs*5 | Frame Shift Ins (INS) | VAF 123/316 reads (39%) | called by mutect2, varscan2
- PRPF40A | c.1718del p.N573Tfs*9 | Frame Shift Del (DEL) | VAF 15/49 reads (31%) | called by mutect2, pindel, varscan2
- PSD3 | c.2240del p.K747Sfs*73 (on ENST00000440756; = p.K746Sfs*73 on NM_015310.4) | Frame Shift Del (DEL) | VAF 58/120 reads (48%) | called by mutect2, varscan2
- RAE1 | c.1052del p.N351Ifs*12 | Frame Shift Del (DEL) | VAF 8/25 reads (32%) | called by mutect2, varscan2
- RB1CC1 | c.2891del p.K964Sfs*13 | Frame Shift Del (DEL) | VAF 63/160 reads (39%) | called by mutect2, pindel, varscan2
- RFESD | c.59_60dup p.G21Wfs*13 | Frame Shift Ins (INS) | VAF 43/103 reads (42%) | called by mutect2, varscan2
- SDK1 | c.657del p.R220Dfs*4 | Frame Shift Del (DEL) | VAF 63/202 reads (31%) | called by mutect2, pindel, varscan2
- SLC46A3 | c.776del p.L259Cfs*9 | Frame Shift Del (DEL) | VAF 12/61 reads (20%) | called by mutect2, pindel, varscan2
- SLC4A1 | c.1749_1751del p.F584del | In Frame Del (DEL) | VAF 10/57 reads (18%) | called by pindel, varscan2
- SNPH | c.235dup p.L79Pfs*30 | Frame Shift Ins (INS) | VAF 10/30 reads (33%) | called by mutect2, pindel, varscan2
- SNX25 | c.1221del p.K407Nfs*6 | Frame Shift Del (DEL) | VAF 35/106 reads (33%) | called by mutect2, pindel, varscan2
- STAT3 | c.380del p.G127Afs*11 | Frame Shift Del (DEL) | VAF 24/57 reads (42%) | called by mutect2, pindel, varscan2
- STT3A | c.1746del p.F582Lfs*113 | Frame Shift Del (DEL) | VAF 59/410 reads (14%) | called by mutect2, pindel, varscan2
- SUV39H2 | c.738del p.G247Afs*19 (on ENST00000354919 / NM_001193424.2; = p.G187Afs*19 on NM_024670.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 63/192 reads (33%) | called by mutect2, pindel, varscan2
- SYCP1 | c.1662dup p.E555Rfs*21 | Frame Shift Ins (INS) | VAF 41/104 reads (39%) | called by mutect2, pindel, varscan2
- TMEM92 | c.357del p.Y120Tfs*4 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | called by mutect2, pindel, varscan2
- USP9X | c.4756_4758del p.L1586del | In Frame Del (DEL) | VAF 35/229 reads (15%) | called by mutect2, pindel, varscan2
- VIRMA | c.2163del p.F721Lfs*11 | Frame Shift Del (DEL) | VAF 87/214 reads (41%) | called by mutect2, varscan2
- VPS13C | c.6908_6909del p.S2303* (on ENST00000644861 / NM_020821.3; = p.S2260* on NM_017684.5) | Frame Shift Del (DEL) | VAF 89/260 reads (34%) | called by mutect2, pindel, varscan2
- VPS35 | c.2106del p.A703Lfs*2 | Frame Shift Del (DEL) | VAF 72/183 reads (39%) | called by mutect2, varscan2
- VPS51 | c.1998del p.S667Vfs*9 | Frame Shift Del (DEL) | VAF 17/49 reads (35%) | called by mutect2, pindel, varscan2
- XKR9 | c.296del p.G99Vfs*27 | Frame Shift Del (DEL) | VAF 77/219 reads (35%) | called by mutect2, pindel, varscan2
- ZBTB1 | c.1571del p.K524Sfs*25 | Frame Shift Del (DEL) | VAF 107/277 reads (39%) | called by mutect2, pindel, varscan2
- ZBTB2 | c.877dup p.L293Pfs*5 | Frame Shift Ins (INS) | VAF 59/158 reads (37%) | called by mutect2, pindel, varscan2
- ZDHHC13 | c.153_154del p.C51* | Frame Shift Del (DEL) | VAF 42/114 reads (37%) | called by pindel, varscan2
- ZIC3 | c.462del p.E155Sfs*68 | Frame Shift Del (DEL) | VAF 6/11 reads (55%) | called by mutect2, varscan2
- ZNF267 | c.464_466del p.S155del | In Frame Del (DEL) | VAF 62/159 reads (39%) | called by pindel, varscan2
- ZNF292 | c.7633del p.R2545Gfs*14 | Frame Shift Del (DEL) | VAF 45/134 reads (34%) | called by mutect2, pindel, varscan2
- ABCC10 | c.2397C>T p.A799= (on ENST00000372530 / NM_001198934.2; = p.A771= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs758138720, COSV55094682; called by muse, mutect2, varscan2
- ABCC11 | c.3504C>T p.H1168= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as rs143002804; called by muse, mutect2, varscan2
- ACOX2 | c.1782C>T p.D594= | Silent (SNP) | VAF 30/77 reads (39%) | catalogued as rs142302007; called by muse, mutect2, varscan2
- ADGRG4 | c.5331T>C p.A1777= | Silent (SNP) | VAF 237/550 reads (43%) | catalogued as COSV54968828; called by muse, mutect2, varscan2
- ADRA2B | c.432G>A p.S144= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as COSV69787632, COSV69788442; called by muse, mutect2, varscan2
- AKAP1 | c.498G>A p.K166= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs1005275327, COSV58473407; called by muse, mutect2, varscan2
- ALDOA | c.585C>T p.D195= (on ENST00000642816 / NM_001243177.4; = p.D141= on NM_184041.5) | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as rs150741747; ClinVar: likely benign; called by muse, mutect2, varscan2
- ANKRD40 | c.648C>T p.S216= | Silent (SNP) | VAF 59/131 reads (45%) | catalogued as COSV53335231; called by muse, mutect2, varscan2
- ATIC | c.417C>T p.H139= | Silent (SNP) | VAF 69/167 reads (41%) | catalogued as rs775773173, COSV52695707; called by muse, mutect2, varscan2
- ATR | c.6705C>T p.S2235= | Silent (SNP) | VAF 37/146 reads (25%) | catalogued as COSV63393519; called by muse, mutect2, varscan2
- BRINP2 | c.624G>A p.T208= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as COSV64180811; called by muse, mutect2, varscan2
- C11orf49 | c.987G>A p.S329= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as rs758619643, COSV53571743; called by muse, mutect2, varscan2
- CACNA1E | c.5221T>C p.L1741= | Silent (SNP) | VAF 56/131 reads (43%) | catalogued as COSV62433579; called by muse, mutect2, varscan2
- CAPZA2 | c.778C>A p.R260= | Silent (SNP) | VAF 48/97 reads (49%) | catalogued as COSV63268164; called by muse, mutect2, varscan2
- CDH18 | c.1824G>A p.S608= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs767007708, COSV56920030; called by muse, mutect2, varscan2
- CDK20 | c.147G>A p.L49= | Silent (SNP) | VAF 66/139 reads (47%) | catalogued as COSV57484665; called by muse, mutect2, varscan2
- CDR1 | c.210G>A p.S70= | Silent (SNP) | VAF 171/415 reads (41%) | catalogued as rs191541717, COSV100983402, COSV65164850; called by muse, mutect2, varscan2
- CEP192 | c.6513G>A p.A2171= | Silent (SNP) | VAF 41/122 reads (34%) | catalogued as rs776814644, COSV58071505; called by muse, mutect2, varscan2
- CHORDC1 | c.765C>T p.S255= | Silent (SNP) | VAF 56/153 reads (37%) | catalogued as rs748091047, COSV57707116; called by muse, mutect2, varscan2
- CHRNA3 | c.981C>T p.N327= | Silent (SNP) | VAF 67/137 reads (49%) | catalogued as rs199707181, COSV58774313; ClinVar: likely benign; called by muse, mutect2, varscan2
- CIPC | c.333G>A p.S111= | Silent (SNP) | VAF 57/111 reads (51%) | catalogued as rs185492654; called by muse, mutect2, varscan2
- CLCA2 | c.111C>T p.D37= | Silent (SNP) | VAF 37/93 reads (40%) | catalogued as COSV65289026; called by muse, mutect2, varscan2
- COPS7A | c.453G>A p.R151= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as COSV57527507; called by muse, mutect2, varscan2
- CRY2 | c.435G>A p.T145= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as rs149135781, COSV101314551; called by muse, mutect2, varscan2
- CST4 | c.270C>T p.G90= | Silent (SNP) | VAF 28/202 reads (14%) | catalogued as COSV54150633; called by muse, mutect2, varscan2
- CST9L | c.78C>A p.I26= | Silent (SNP) | VAF 38/78 reads (49%) | catalogued as COSV65408267, COSV65408449; called by muse, mutect2, varscan2
- CSTL1 | c.366C>T p.P122= | Silent (SNP) | VAF 46/116 reads (40%) | catalogued as COSV55678874, COSV55678907; called by muse, mutect2, varscan2
- CTCFL | c.1173G>A p.T391= | Silent (SNP) | VAF 29/63 reads (46%) | catalogued as rs376178878, COSV99713290; called by muse, mutect2, varscan2
- CTNNBL1 | c.714G>A p.Q238= | Silent (SNP) | VAF 74/180 reads (41%) | catalogued as COSV63744676; called by muse, mutect2, varscan2
- DCAF4L2 | c.1077G>A p.S359= | Silent (SNP) | VAF 40/78 reads (51%) | catalogued as rs754142692, COSV60483251; called by muse, mutect2, varscan2
- DCUN1D1 | c.417C>A p.A139= | Silent (SNP) | VAF 275/625 reads (44%) | catalogued as COSV53046452; called by muse, mutect2, varscan2
- DOK1 | c.678A>G p.S226= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV51215892; called by muse, mutect2, varscan2
- DSG2 | c.582G>A p.S194= | Silent (SNP) | VAF 61/142 reads (43%) | catalogued as rs748768578, COSV55198230; called by muse, mutect2, varscan2
- DTNA | c.342C>T p.F114= | Silent (SNP) | VAF 74/188 reads (39%) | catalogued as COSV52011716; called by muse, mutect2, varscan2
- DYNC1H1 | c.8190C>T p.H2730= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as rs747028073, COSV64143726; called by muse, mutect2, varscan2
- EDC4 | c.2013C>T p.G671= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs56971448; called by muse, mutect2
- EDEM3 | c.279C>T p.R93= | Silent (SNP) | VAF 34/81 reads (42%) | catalogued as rs766444517, COSV58924951, COSV58926867; called by muse, mutect2, varscan2
- EEF1AKMT4 | c.642C>T p.G214= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs757100745, COSV56182501; called by muse, mutect2, varscan2
- EPHA1 | c.1666C>T p.L556= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV51977148; called by muse, mutect2, varscan2
- EPHB1 | c.2283C>T p.S761= | Silent (SNP) | VAF 172/422 reads (41%) | catalogued as rs555858727, COSV101213411, COSV67654919; called by muse, mutect2, varscan2
- ESPL1 | c.3972C>T p.A1324= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as COSV57763927; called by muse, mutect2, varscan2
- FAM189A2 | c.966G>A p.P322= | Silent (SNP) | VAF 31/66 reads (47%) | catalogued as rs755452769, COSV57385268; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAM47A | c.1095G>A p.A365= | Silent (SNP) | VAF 82/181 reads (45%) | catalogued as rs1375077987, COSV60498823; called by muse, mutect2, varscan2
- FETUB | c.213G>A p.Q71= | Silent (SNP) | VAF 6/148 reads (4%) | catalogued as COSV54007421; called by muse, mutect2
- FLG | c.11550A>G p.S3850= | Silent (SNP) | VAF 154/360 reads (43%) | catalogued as COSV64251185; called by muse, mutect2, varscan2
- FRAS1 | c.9789C>T p.D3263= | Silent (SNP) | VAF 35/87 reads (40%) | catalogued as COSV53654226; called by muse, mutect2, varscan2
- FRMPD3 | c.3745C>T p.L1249= | Silent (SNP) | VAF 42/103 reads (41%) | catalogued as COSV52197989; called by muse, mutect2, varscan2
- GOLGA8A | c.729C>T p.H243= (on ENST00000432566; = p.H215= on NM_181077.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs1466138043, COSV62171674; called by mutect2, varscan2
- GPRIN1 | c.159C>T p.S53= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs752798153, COSV56146222; called by muse, mutect2, varscan2
- HFM1 | c.3105C>T p.D1035= | Silent (SNP) | VAF 39/84 reads (46%) | catalogued as rs748543481, COSV54036743, COSV99646149; called by muse, mutect2, varscan2
- HMG20A | c.768C>T p.H256= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as rs767735573, COSV60314487; called by muse, mutect2, varscan2
- HSPB8 | c.186C>T p.G62= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as COSV56139612; called by muse, mutect2, varscan2
- IFNGR2 | c.336T>G p.T112= | Silent (SNP) | VAF 19/109 reads (17%) | catalogued as COSV51641533; called by muse, mutect2, varscan2
- IL1F10 | c.318A>G p.S106= | Silent (SNP) | VAF 118/241 reads (49%) | catalogued as COSV61751074; called by muse, mutect2, varscan2
- INTS1 | c.243C>A p.S81= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV67178111; called by muse, mutect2, varscan2
- IP6K2 | c.1098C>A p.A366= | Silent (SNP) | VAF 29/70 reads (41%) | catalogued as COSV53664080; called by muse, mutect2, varscan2
- ITGA7 | c.993C>T p.R331= (on ENST00000555728; = p.R287= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs773176669, COSV57701661, COSV57701835; called by muse, mutect2, varscan2
- ITPR3 | c.6204G>A p.Q2068= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as COSV65415523; called by muse, mutect2, varscan2
- KAT2A | c.1527G>A p.T509= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs200523371; called by muse, mutect2, varscan2
- KCND3 | c.51C>T p.I17= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs748795678, COSV56190902; called by muse, mutect2, varscan2
- KIF1A | c.1110C>T p.R370= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as rs369641508; ClinVar: likely benign; called by muse, mutect2, varscan2
- KRT25 | c.393C>T p.S131= | Silent (SNP) | VAF 137/311 reads (44%) | catalogued as COSV56445338; called by muse, mutect2, varscan2
- LDHAL6B | c.282T>C p.S94= | Silent (SNP) | VAF 79/199 reads (40%) | catalogued as COSV55696856; called by muse, mutect2, varscan2
- LRP2 | c.7515C>T p.R2505= | Silent (SNP) | VAF 100/236 reads (42%) | catalogued as rs773316402, COSV55564114; called by muse, mutect2, varscan2
- LSS | c.1053C>T p.D351= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as rs766693962, COSV62700138; called by muse, mutect2, varscan2
- LTA | c.516G>A p.A172= | Silent (SNP) | VAF 39/136 reads (29%) | catalogued as rs368380570; called by muse, mutect2, varscan2
- MAGEH1 | c.165G>A p.P55= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV61678730; called by muse, mutect2, varscan2
- MAN2A1 | c.228C>T p.V76= | Silent (SNP) | VAF 129/303 reads (43%) | catalogued as COSV54859535; called by muse, mutect2, varscan2
- MAN2A1 | c.2823G>T p.G941= | Silent (SNP) | VAF 130/342 reads (38%) | catalogued as COSV54859544; called by muse, mutect2, varscan2
- MED24 | c.2220C>T p.G740= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs753068864, COSV62420176; called by muse, mutect2, varscan2
- MTRF1 | c.936G>A p.G312= | Silent (SNP) | VAF 92/219 reads (42%) | catalogued as COSV65263947; called by muse, mutect2, varscan2
- MUC16 | c.34530C>A p.S11510= | Silent (SNP) | VAF 178/439 reads (41%) | catalogued as COSV67499098; called by muse, mutect2, varscan2
- NOP14 | c.540C>T p.G180= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as rs1178322441, COSV58628296; called by muse, mutect2, varscan2
- NXPH3 | c.213G>A p.P71= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs551752487, COSV100165600, COSV60871966; called by muse, mutect2, varscan2
- OBSCN | c.3528G>A p.V1176= | Silent (SNP) | VAF 47/118 reads (40%) | catalogued as COSV52838688; called by muse, mutect2, varscan2
- PASK | c.2550G>A p.T850= | Silent (SNP) | VAF 51/108 reads (47%) | catalogued as rs764571398, COSV52151594; called by muse, mutect2, varscan2
- PCDH19 | c.339C>T p.C113= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs757433043, COSV55272774; called by muse, mutect2, varscan2
- PCDHA2 | c.1509G>A p.A503= | Silent (SNP) | VAF 18/31 reads (58%) | catalogued as COSV100974195, COSV65368060; called by muse, mutect2, varscan2
- PCDHGB7 | c.1347G>A p.A449= | Silent (SNP) | VAF 35/82 reads (43%) | catalogued as COSV54048152; called by muse, mutect2, varscan2
- PCYT2 | c.138G>A p.R46= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs773012566, COSV58712391; called by muse, mutect2, varscan2
- PIPOX | c.255A>G p.Q85= | Silent (SNP) | VAF 37/82 reads (45%) | catalogued as rs201240164, COSV60143995; called by muse, mutect2, varscan2
- PLEKHM1 | c.348C>T p.G116= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV69599534; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1731C>T p.A577= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs143001269; called by muse, mutect2, varscan2
- RAB28 | c.345C>T p.S115= | Silent (SNP) | VAF 27/239 reads (11%) | catalogued as rs779235223, COSV56543198; called by muse, mutect2, varscan2
- RASA3 | c.501C>T p.Y167= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs200944524, COSV61874485; called by muse, mutect2, varscan2
- RBM33 | c.3294C>T p.C1098= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs1211615158, COSV62031415; called by muse, mutect2, varscan2
- RET | c.2289C>T p.N763= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs777349208, COSV60698344, COSV60710440; ClinVar: likely benign; called by muse, mutect2, varscan2
- RMND5B | c.345G>A p.Q115= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV57746542; called by muse, mutect2, varscan2
- RPGRIP1L | c.2907A>G p.T969= | Silent (SNP) | VAF 49/109 reads (45%) | catalogued as COSV50919649; called by muse, mutect2, varscan2
- RPUSD3 | c.342G>A p.L114= | Silent (SNP) | VAF 103/252 reads (41%) | catalogued as rs1242298017, COSV67579591; called by muse, mutect2, varscan2
- RRBP1 | c.3525G>A p.K1175= (on ENST00000377813 / NM_001365613.2; = p.K742= on NM_004587.3) | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as rs756142641, COSV55709577; called by muse, mutect2, varscan2
- RRP1B | c.648C>A p.V216= | Silent (SNP) | VAF 61/133 reads (46%) | catalogued as COSV61480741; called by muse, mutect2, varscan2
- SALL1 | c.1644G>A p.L548= | Silent (SNP) | VAF 43/93 reads (46%) | catalogued as COSV51765292; called by muse, mutect2, varscan2
- SEPTIN1 | c.261C>T p.T87= (on ENST00000321367; = p.T40= on NM_052838.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs1369194943, COSV58444098; called by muse, mutect2, varscan2
- SLC25A33 | c.579G>A p.S193= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as rs370298864, COSV57022123; called by muse, mutect2, varscan2
- SLC45A3 | c.1501C>T p.L501= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as COSV65655685; called by muse, mutect2, varscan2
- SPECC1 | c.1260G>A p.T420= | Silent (SNP) | VAF 73/159 reads (46%) | catalogued as rs554639225, COSV54953107, COSV99821380; called by muse, mutect2, varscan2
- SPRY4 | c.207C>T p.G69= (on ENST00000434127 / NM_001127496.3; = p.G92= on NM_030964.4) | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs370041280, COSV59986945; called by muse, mutect2, varscan2
- SRA1 | c.417A>G p.R139= | Silent (SNP) | VAF 54/116 reads (47%) | catalogued as COSV51860173; called by muse, mutect2, varscan2
- STAM2 | c.1434A>G p.T478= | Silent (SNP) | VAF 29/205 reads (14%) | catalogued as COSV55734415; called by muse, mutect2, varscan2
- STRIP2 | c.372G>A p.R124= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as rs779136915, COSV50810048; called by muse, mutect2, varscan2
- SVEP1 | c.2385C>T p.H795= | Silent (SNP) | VAF 130/265 reads (49%) | catalogued as rs770858847, COSV57049660; called by muse, mutect2, varscan2
- TCP1 | c.1488A>G p.R496= | Silent (SNP) | VAF 95/216 reads (44%) | catalogued as COSV58460661; called by muse, mutect2, varscan2
- TFAP2B | c.534C>T p.D178= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV53832073; called by muse, mutect2
- THOC2 | c.1728A>G p.P576= | Silent (SNP) | VAF 119/304 reads (39%) | catalogued as COSV55556921; called by muse, mutect2, varscan2
- TIAM1 | c.3165C>T p.Y1055= | Silent (SNP) | VAF 45/86 reads (52%) | catalogued as rs373676358; called by muse, mutect2, varscan2
- TMEM25 | c.639C>T p.D213= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs782728974, COSV57096651; called by muse, mutect2, varscan2
- TNS3 | c.1455C>T p.H485= | Silent (SNP) | VAF 21/34 reads (62%) | catalogued as rs745634291, COSV60791397; called by muse, mutect2, varscan2
- TOP3B | c.1638C>T p.H546= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs761413733, COSV64119433; called by muse, mutect2, varscan2
- TP63 | c.1581C>G p.P527= | Silent (SNP) | VAF 78/146 reads (53%) | catalogued as rs61752082, COSV53222785; called by muse, mutect2, varscan2
- TRAV27 | c.192G>T p.L64= | Silent (SNP) | VAF 81/143 reads (57%) | called by muse, mutect2, varscan2
- TRIM26 | c.1002C>T p.C334= | Silent (SNP) | VAF 38/100 reads (38%) | catalogued as rs1396875438, COSV70983628; called by muse, varscan2
- TTN | c.31242C>T p.H10414= (on ENST00000591111; = p.H9487= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as rs1002677056, COSV60391929; called by muse, mutect2, varscan2
- UBE2Q2 | c.744T>C p.P248= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as COSV51197153; called by muse, mutect2, varscan2
- UGT1A1 | c.1038G>A p.A346= | Silent (SNP) | VAF 108/241 reads (45%) | catalogued as rs770433443, COSV59386634, COSV59393460; called by muse, mutect2, varscan2
- WWC3 | c.954C>T p.S318= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as rs751377385, COSV66508438; called by muse, mutect2
- ZC3H12A | c.201C>T p.S67= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as rs201308864, COSV66104646; called by muse, mutect2, varscan2
- ZFHX3 | c.4344T>C p.L1448= | Silent (SNP) | VAF 111/302 reads (37%) | catalogued as COSV51739098; called by muse, mutect2, varscan2
- ZNF28 | c.519A>G p.S173= | Silent (SNP) | VAF 17/370 reads (5%) | catalogued as COSV60425837; called by muse, mutect2
- ZNF37A | c.1551C>T p.H517= | Silent (SNP) | VAF 50/128 reads (39%) | catalogued as rs1295126656, COSV61075922; called by muse, mutect2, varscan2
- ZNF454 | c.411G>A p.L137= | Silent (SNP) | VAF 40/96 reads (42%) | catalogued as COSV60770593; called by muse, mutect2, varscan2
- ZNF526 | c.657C>T p.H219= | Silent (SNP) | VAF 53/117 reads (45%) | catalogued as rs762709335, COSV56631731; called by muse, mutect2, varscan2
- ZNF761 | c.1149A>G p.K383= | Silent (SNP) | VAF 234/453 reads (52%) | catalogued as rs879234577, COSV61887919; called by muse, mutect2, varscan2
- ZNF778 | c.1728A>G p.L576= | Silent (SNP) | VAF 67/255 reads (26%) | catalogued as COSV60603093; called by muse, mutect2, varscan2
- ZNF831 | c.222C>T p.R74= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs763329350, COSV64040907, COSV64042592; called by muse, mutect2, varscan2
- ZSCAN20 | c.1767G>A p.R589= | Silent (SNP) | VAF 72/197 reads (37%) | catalogued as rs377448219; called by muse, mutect2, varscan2
- AC024940.1 | n.1086T>C | RNA (SNP) | VAF 12/21 reads (57%) | called by muse, mutect2, varscan2
- AK9 | c.3633+13_3633+16del | Intron (DEL) | VAF 25/70 reads (36%) | catalogued as rs766264675; called by pindel, varscan2
- AL353804.7 | chrX:73851927 del A | 3'Flank (DEL) | VAF 60/143 reads (42%) | catalogued as rs760456851; called by mutect2, varscan2
- ANKRD33 | c.-110del | 5'UTR (DEL) | VAF 12/44 reads (27%) | catalogued as rs866543330, COSV100001143; called by mutect2, pindel, varscan2
- DCHS2 | n.7559del | RNA (DEL) | VAF 71/184 reads (39%) | catalogued as CD1514800; called by mutect2, pindel, varscan2
- FAM83G | c.2082+608G>A | Intron (SNP) | VAF 6/14 reads (43%) | catalogued as rs61738464; called by muse, mutect2
- FGFR2 | c.748+195A>G | Intron (SNP) | VAF 33/82 reads (40%) | catalogued as COSV60660224; called by muse, mutect2, varscan2
- KCNH4 | c.-2C>T | 5'UTR (SNP) | VAF 16/47 reads (34%) | catalogued as rs1462597156, COSV99236967; called by muse, mutect2, varscan2
- LINC01600 | n.864C>T | RNA (SNP) | VAF 29/68 reads (43%) | catalogued as rs547228602; called by muse, mutect2, varscan2
- MACROH2A1 | c.688+2080C>T | Intron (SNP) | VAF 19/44 reads (43%) | catalogued as COSV56898452; called by muse, mutect2, varscan2
- MFSD4B | c.*303del | 3'UTR (DEL) | VAF 60/145 reads (41%) | catalogued as rs760972171; called by mutect2, pindel, varscan2
- NBPF11 | c.-548-3027C>T | Intron (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- NUDCD3 | c.509+16882del | Intron (DEL) | VAF 125/339 reads (37%) | called by mutect2, pindel, varscan2
- PCDHGA9 | c.2424+17del | Intron (DEL) | VAF 34/87 reads (39%) | catalogued as rs759226115; called by mutect2, varscan2
- RALGAPA1 | c.*76T>C | 3'UTR (SNP) | VAF 44/100 reads (44%) | catalogued as COSV51899090; called by muse, mutect2, varscan2
- SGIP1 | c.99+999del | Intron (DEL) | VAF 18/35 reads (51%) | catalogued as rs745636084, COSV52764888; called by mutect2, varscan2
